Somatic mutation profile of tumor specimen 0DTNWF from CCDI case PBCJPJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.5 years (178 days).
Specimen 0DTNWF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e8c74c5-468a-4b6a-ae1c-6de5cb7c4142.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTNX9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47afd880-466f-4239-97f4-959ed5ad8563

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD20A4P | c.2088A>T p.Q696H | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs75696372; called by muse, varscan2
- DOCK9 | c.4827G>T p.T1609= (on ENST00000376460 / NM_001366676.2; = p.T1610= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 199/1806 reads (11%) | catalogued as rs759695289; called by muse, mutect2, varscan2
